Gene-level copy-number profile of tumor specimen TCGA-D7-6528-01A from TCGA case TCGA-D7-6528, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.7 years (25,815 days).
Specimen TCGA-D7-6528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.15f15f52-25bd-4970-bbb2-4622b639226a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6528-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe0e6327-e0bb-41ce-8d1e-a25f549abc9d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 2: 9,532; copy number 3: 18,461; copy number 4: 13,784; copy number 5: 12,483; copy number 6: 3,632; copy number 7: 1,264; copy number 8: 81; copy number 9: 66; copy number 10: 26; copy number 11: 104; copy number 13: 80; copy number 14: 22; copy number 15: 57; copy number 16: 11; copy number 17: 8; copy number 19: 140; copy number 26: 9; copy number 43: 2; copy number 46: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6528-01A-11D-1799-01): tumor purity 0.62, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:188,153,284–188,890,671, 1 gene (within-gene range 0–4): LPP.
- chr3:188,562,238–188,688,866, 2 genes: LPP-AS1, MIR28.
- chr4:7,754,077–7,939,926, 3 genes (within-gene range 0–2): AFAP1-AS1, AFAP1, AC112254.1.
- chr10:74,506,081–75,431,588, 29 genes: AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,743,755, 5 genes: AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,752 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,222,913–33,200,665, 174 genes, copy number 11–19 (broad region; genes not listed).
- chr6:41,026,895–44,830,188, 149 genes, copy number 11–13 (broad region; genes not listed).
- chr6:44,898,711–44,899,295, 1 gene, copy number 13: NUDT19P4.
- chr7:116,524,994–124,489,572, 110 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr10:29,891,032–30,115,494, 2 genes, copy number 43: AL353093.1, JCAD.
- chr10:30,380,174–35,898,963, 99 genes, copy number 10–46 (broad region; genes not listed).
- chr10:73,005,833–74,709,963, 66 genes, copy number 9 (within-gene range 0–9) (broad region; genes not listed).
- chr19:29,205,320–30,228,715, 28 genes, copy number 16–26: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr20:18,090,116–64,313,132, 1,123 genes, copy number 7–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
